TCGA case TCGA-G8-6907 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31bbad4e-3789-42ec-9faa-1cb86970f723

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 595 days (1.6 years).

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 57.6 years (21,021 days); Year of diagnosis: 2000; AJCC staging edition: 5th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Cervical.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP; Days to treatment start: 28 days; Days to treatment end: 187 days; Number of cycles: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cytarabine + Dexamethasone + Rituximab; Initial disease status: Progressive Disease; Regimen or line of therapy: R-DHAC; Days to treatment start: 288 days; Days to treatment end: 327 days; Number of cycles: 2.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 383 days (1.0 years); Days to treatment end: 385 days (1.1 years); Treatment dose: 1,000 cGy; Course number: 1; Number of fractions: 5.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 386 days (1.1 years).
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Ovary. Age at diagnosis: 58.3 years (21,300 days); Days to diagnosis: 279 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 279 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Ovary; Days to progression: 279 days.
- Days to follow up: 595 days (1.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2 (PCR): Normal.
- CD10 (IHC): Positive.
- CD20 (IHC): Positive.
- CD23 (IHC): Negative.
- CD5 (IHC): Negative.
- Lactate Dehydrogenase 628 IU [Blood test normal range upper: 618].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91.8 kg; Height: 154.2 cm; BMI: 38.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.3; Shortest dimension: 0.1.
  Slide TCGA-G8-6907-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 90.
- Sample TCGA-G8-6907-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6907-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Stable Disease.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology: Extranodal site involvement: 0; Bone marrow biopsy performed: Yes.
- Tests performed: LDH level: 628; B cell genotype method: IgH Southern Blot.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: CD23; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD5; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: BCL2.
- Drug treatment 1: Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: DHAC + Rituxan.
- Drug treatment 2: Pharmaceutical therapy drug name: High dose ara-c; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: DHAC + Rituxan.
- Drug treatment 3: Pharmaceutical therapy drug name: Rituxan; Stem cell transplantation: Yes; Stem cell transplantation type: Autologous; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: DHAC + Rituxan.
- Drug treatment 5: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP- Not specified.
- Drug treatment 8: Pharmaceutical therapy drug name: Adriamycin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOP- Not specified.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 595 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 595 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 279 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G8-6907-01A-11D-2209-01): tumor purity 0.94, ploidy 1.98, whole-genome doublings 0.
